Gene-level copy-number profile of tumor specimen TCGA-5A-A8ZG-01A from TCGA case TCGA-5A-A8ZG, project TCGA-CHOL (Cholangiocarcinoma).
Specimen TCGA-5A-A8ZG-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 71b59c5d-6236-48f0-a448-ee0cdd3e0156.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator TCGA-5A-A8ZG-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,709 have no estimate.
https://portal.gdc.cancer.gov/files/ce2690b6-9724-4651-bfed-049f319c00bb

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 71; copy number 1: 5,801; copy number 2: 52,252; copy number 3: 790.

Homozygous deletions (total copy number 0; autosomes only): 71 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:20,999,509–24,592,104, 70 genes (broad region; genes not listed).
- chr21:12,999,676–13,016,692, 1 gene: AP001464.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 2,945. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
